Gene-level copy-number profile of tumor specimen TCGA-CC-A8HV-01A from TCGA case TCGA-CC-A8HV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 51.8 years (18,935 days).
Specimen TCGA-CC-A8HV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.b10fd2ba-67a5-4092-8870-35536f11e941.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A8HV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/49c14f67-dd0d-41e7-905a-4b74755e39b2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 2,194; copy number 2: 14,128; copy number 3: 11,105; copy number 4: 19,673; copy number 5: 7,512; copy number 6: 1,872; copy number 7: 2,481; copy number 8: 355; copy number 9: 437; copy number 10: 6; copy number 11: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A8HV-01A-11D-A40C-01): tumor purity 0.82, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:33,043,609–33,991,551, 44 genes (within-gene range 0–2): AC145350.2, HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.6, AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3, AC142384.1, BMS1P8, AC136428.4, ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 451 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,140,491–157,898,256, 256 genes, copy number 9 (broad region; genes not listed).
- chr1:194,188,967–195,763,501, 6 genes, copy number 9: EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1, AL353072.2, AL353709.1.
- chr1:214,870,734–217,137,755, 14 genes, copy number 9–11: GAPDHP24, AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG.
- chr1:238,238,943–241,357,230, 41 genes, copy number 9–10 (within-gene range 7–10): AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123.
- chr3:88,948,142–90,261,708, 10 genes, copy number 9: ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:39,399,149–40,630,875, 41 genes, copy number 9 (within-gene range 6–9): RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1, UGDH, UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2, UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP, PDS5A, ELOCP33, RNA5SP159, AC098591.3, PABPC1P1, KRT18P25, AC098591.2, N4BP2, RNU6-1112P, AC098591.1, AC095057.1, AC095057.3, AC095057.4, RHOH, AC095057.2, LINC02265, CHRNA9, RNU7-74P, RBM47, AC098869.2, AC098869.1, MIR4802.
- chr8:137,424,904–138,497,261, 7 genes, copy number 9: ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B.
- chr10:72,501,746–74,150,842, 76 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
